Somatic mutation profile of tumor specimen MMRF_1445_1_BM_CD138pos (aliquot MMRF_1445_1_BM_CD138pos_T1_KAS5U_L01376) from MMRF case MMRF_1445, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.4 years (28,253 days).
Specimen MMRF_1445_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49aa11ef-22b4-4b5c-97a3-8ddbf3b38c9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1445_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1445_1_PB_Whole_C2_KAS5U_L01388; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e21589bb-138a-4bdc-95f7-1e5745a77ac9

The open-access MAF lists 119 somatic variants for this specimen: 46 protein-altering or splice-affecting, 17 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 31, Silent 17, Intron 12, 5'Flank 5, 5'UTR 5, 3'Flank 3, Nonsense Mutation 2, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTG1 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs533912735, COSV55457953, COSV55458217, COSV55458575; called by muse, mutect2, varscan2
- CDA | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as rs1557548856; called by muse, mutect2, varscan2
- CEP131 | c.1852C>T p.R618W (on ENST00000269392 / NM_001319228.2; = p.R615W on NM_014984.4) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as rs907088497, COSV53955643; called by muse, mutect2
- DENND2C | c.2458G>A p.E820K (on ENST00000393274 / NM_001256404.2; = p.E763K on NM_198459.4) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780932484, COSV67921285; called by muse, mutect2, varscan2
- E2F7 | c.2567C>T p.S856L | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs200694984, COSV100523285; called by muse, mutect2, varscan2
- EPB41L3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1352407489; called by muse, mutect2
- FGL2 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 103/190 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.41); catalogued as rs766228164; called by muse, mutect2, varscan2
- IER2 | c.286A>T p.M96L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.174); catalogued as COSV52848514; called by muse, varscan2
- IGHV2-70 | c.316A>C p.M106L | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.073); catalogued as rs373599438; called by muse, varscan2
- IGLV2-11 | c.323A>T p.Y108F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.166); catalogued as rs761340679; called by muse, mutect2, varscan2
- MCOLN3 | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 130/221 reads (59%) | catalogued as COSV100352842; called by muse, mutect2, varscan2
- MYH4 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV99702618; called by muse, mutect2, varscan2
- NFATC2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.051); catalogued as COSV69014131; called by muse, mutect2
- PACC1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.418); catalogued as rs778308357, COSV54788298; called by muse, mutect2, varscan2
- PCDHA4 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.013); catalogued as rs782333816, COSV63542636; called by muse, mutect2, varscan2
- PRDM8 | c.552C>A p.S184R | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.238); catalogued as rs767040118; called by muse, mutect2, varscan2
- PTPRF | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs1160984093, COSV100741219; called by muse, mutect2, varscan2
- SFMBT2 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV62811726; called by muse, mutect2, varscan2
- ADGRV1 | c.7780T>A p.L2594I | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- AGXT2 | c.1339A>G p.I447V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.8885A>T p.K2962M | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- BTG1 | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CAMK4 | c.798G>A p.W266* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- CLIP1 | c.660T>C p.V220= | Splice Region (SNP) | VAF 51/107 reads (48%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.1897G>T p.V633L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNHD1 | c.4169dup p.H1390Qfs*14 | Frame Shift Ins (INS) | VAF 35/67 reads (52%) | called by mutect2, pindel, varscan2
- GPR107 | c.1737G>A p.M579I (on ENST00000372406 / NM_001136557.2; = p.M531I on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2
- LSS | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- LUZP2 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2AG2 | c.442T>G p.S148A | Missense Mutation (SNP) | VAF 58/58 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR5H14 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLS3 | c.875T>C p.F292S | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTER | c.710A>T p.D237V | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- RAB25 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- RNFT2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPE65 | c.1226T>C p.F409S | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SEL1L | c.207A>T p.E69D | Missense Mutation (SNP) | VAF 114/114 reads (100%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINA3 | c.1250T>C p.V417A | Missense Mutation (SNP) | VAF 54/56 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SIPA1L2 | c.4339G>A p.V1447I | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC12A1 | c.2489A>G p.E830G | Missense Mutation (SNP) | VAF 95/218 reads (44%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SLC9A9 | c.1688T>C p.L563P | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- TENM2 | c.6799G>A p.D2267N (on ENST00000518659 / NM_001122679.2; = p.D2028N on NM_001080428.3) | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TERF1 | c.1202G>T p.G401V (on ENST00000276603 / NM_017489.3; = p.G381V on NM_003218.4) | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWC2 | c.80G>A p.C27Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ZNF330 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.192); called by muse, mutect2
- ZNF469 | c.1548_1554dup p.G519Qfs*221 | Frame Shift Ins (INS) | VAF 37/50 reads (74%) | called by mutect2, varscan2
- BAHCC1 | c.2415C>A p.G805= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- DSC1 | c.576G>C p.G192= | Silent (SNP) | VAF 30/324 reads (9%) | called by muse, mutect2
- EPPK1 | c.2898C>G p.A966= | Silent (SNP) | VAF 27/27 reads (100%) | called by muse, mutect2, varscan2
- GASK1B | c.1044A>T p.R348= | Silent (SNP) | VAF 58/128 reads (45%) | catalogued as rs1184952932; called by muse, mutect2, varscan2
- IER2 | c.285A>T p.P95= | Silent (SNP) | VAF 30/66 reads (45%) | called by muse, varscan2
- IGLV3-1 | c.153T>A p.A51= | Silent (SNP) | VAF 64/65 reads (98%) | catalogued as rs571682243; called by muse, mutect2, varscan2
- MYOF | c.507A>T p.P169= | Silent (SNP) | VAF 18/473 reads (4%) | called by muse, mutect2
- NCOR2 | c.3198C>T p.S1066= | Silent (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- NRK | c.4191G>A p.L1397= | Silent (SNP) | VAF 43/54 reads (80%) | called by muse, mutect2, varscan2
- PCDHA4 | c.2253G>A p.S751= | Silent (SNP) | VAF 46/82 reads (56%) | catalogued as COSV100793561, COSV63544105; called by muse, mutect2, varscan2
- PTPN13 | c.7164G>T p.L2388= (on ENST00000411767 / NM_080683.3; = p.L2369= on NM_006264.3) | Silent (SNP) | VAF 105/227 reads (46%) | catalogued as rs368958959; called by muse, mutect2, varscan2
- RALGDS | c.399G>A p.Q133= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV100924534; called by muse, mutect2, varscan2
- RPP14 | c.51C>T p.S17= | Silent (SNP) | VAF 197/403 reads (49%) | catalogued as rs761751734; called by muse, mutect2, varscan2
- S100A3 | c.9G>A p.R3= | Silent (SNP) | VAF 62/193 reads (32%) | called by muse, mutect2, varscan2
- SNCAIP | c.987A>G p.G329= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- TP53I11 | c.540C>T p.Y180= | Silent (SNP) | VAF 68/70 reads (97%) | catalogued as rs1463804412; called by muse, mutect2, varscan2
- WNT5A | c.861C>T p.V287= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as COSV99224932; called by muse, mutect2, varscan2
- AC020637.1 | n.801-470A>T | Intron (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- ADK | c.*328A>G | 3'UTR (SNP) | VAF 38/72 reads (53%) | catalogued as rs1469584602; called by muse, mutect2, varscan2
- ALOX12B | c.-138C>T | 5'UTR (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2
- ARHGAP4 | c.-9G>A | 5'UTR (SNP) | VAF 59/81 reads (73%) | catalogued as rs1186864948; called by muse, mutect2, varscan2
- ARHGEF1 | c.1122-336C>T | Intron (SNP) | VAF 42/75 reads (56%) | catalogued as rs1021195976; called by muse, mutect2, varscan2
- BCL7A | chr12:122020995 C>G | 5'Flank (SNP) | VAF 61/126 reads (48%) | catalogued as COSV55849233, COSV55850852; called by muse, mutect2, varscan2
- BMP6 | c.*1095G>A | 3'UTR (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- C4orf50 | c.*1844C>A | 3'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- CARTPT | c.*257T>G | 3'UTR (SNP) | VAF 59/105 reads (56%) | called by muse, mutect2, varscan2
- CCSER1 | c.2010+3253A>C | Intron (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- CFHR4 | c.-84C>T | 5'UTR (SNP) | VAF 31/643 reads (5%) | called by muse, mutect2
- CIT | c.*822G>A | 3'UTR (SNP) | VAF 10/86 reads (12%) | catalogued as rs1206780809; called by muse, mutect2, varscan2
- CUX1 | c.*5642T>G | 3'UTR (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- CXorf38 | c.*1+192T>G | Intron (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- FMN2 | c.*904G>T | 3'UTR (SNP) | VAF 87/151 reads (58%) | catalogued as COSV100146841; called by muse, mutect2, varscan2
- GASK1A | c.-108C>G | 5'UTR (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2
- GLIPR2 | chr9:36136721 G>A | 5'Flank (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2
- GPC3 | c.*238A>C | 3'UTR (SNP) | VAF 5/45 reads (11%) | catalogued as rs1424856028; called by muse, mutect2
- GYPB | c.*190A>C | 3'UTR (SNP) | VAF 53/114 reads (46%) | called by muse, varscan2
- IFNG | c.*41C>T | 3'UTR (SNP) | VAF 135/280 reads (48%) | called by muse, mutect2, varscan2
- IGDCC3 | c.*1683C>T | 3'UTR (SNP) | VAF 47/78 reads (60%) | catalogued as rs940354779; called by muse, mutect2, varscan2
- JPH4 | c.*271C>T | 3'UTR (SNP) | VAF 21/22 reads (95%) | called by muse, mutect2, varscan2
- KCNAB1 | c.*333C>A | 3'UTR (SNP) | VAF 47/81 reads (58%) | called by muse, mutect2, varscan2
- KCNMB3 | chr3:179240116 T>A | 3'Flank (SNP) | VAF 63/128 reads (49%) | called by muse, mutect2, varscan2
- KCNMB3 | chr3:179240117 A>G | 3'Flank (SNP) | VAF 62/126 reads (49%) | catalogued as COSV55939265; called by muse, mutect2, varscan2
- LGI1 | c.*131G>A | 3'UTR (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- LSP1 | c.54-9628A>G | Intron (SNP) | VAF 51/93 reads (55%) | called by muse, mutect2, varscan2
- MIB1 | c.1829+5913A>C | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- MSL3 | c.102+296C>T | Intron (SNP) | VAF 32/45 reads (71%) | catalogued as COSV56493151; called by muse, mutect2, varscan2
- MTMR1 | c.*9-195G>T | Intron (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- OPCML | c.*287T>C | 3'UTR (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2
- PGAP4 | c.*1616C>T | 3'UTR (SNP) | VAF 53/99 reads (54%) | called by muse, mutect2, varscan2
- PIK3CA | c.*5462T>C | 3'UTR (SNP) | VAF 124/304 reads (41%) | called by muse, varscan2
- PIK3CA | c.*5539T>C | 3'UTR (SNP) | VAF 104/211 reads (49%) | called by muse, varscan2
- POLK | c.*736A>G | 3'UTR (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- PRPS1 | c.405+11A>G | Intron (SNP) | VAF 37/152 reads (24%) | called by muse, mutect2, varscan2
- RBM24 | c.*939T>C | 3'UTR (SNP) | VAF 52/96 reads (54%) | catalogued as rs1038074433; called by muse, varscan2
- RFX4 | c.-165C>A | 5'UTR (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- RIOK3 | c.*1757C>G | 3'UTR (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- RNASEK | c.196-313A>T | Intron (SNP) | VAF 59/103 reads (57%) | called by muse, mutect2, varscan2
- SEPTIN10 | c.30+665C>T | Intron (SNP) | VAF 178/371 reads (48%) | called by muse, mutect2, varscan2
- SGK1 | c.787-112T>C | Intron (SNP) | VAF 31/45 reads (69%) | catalogued as rs1403463524; called by muse, mutect2, varscan2
- SLAIN2 | c.*1917_*1923del | 3'UTR (DEL) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- SOX6 | chr11:15970648 T>G | 3'Flank (SNP) | VAF 73/74 reads (99%) | called by muse, mutect2, varscan2
- THAP1 | c.*511T>A | 3'UTR (SNP) | VAF 166/243 reads (68%) | called by muse, mutect2, varscan2
- THRB | c.*1999G>C | 3'UTR (SNP) | VAF 67/135 reads (50%) | called by muse, mutect2, varscan2
- TK1 | c.*412C>G | 3'UTR (SNP) | VAF 57/109 reads (52%) | called by muse, mutect2, varscan2
- TMCO5A | c.*985A>C | 3'UTR (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975332 C>G | 5'Flank (SNP) | VAF 78/105 reads (74%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975447 T>G | 5'Flank (SNP) | VAF 75/95 reads (79%) | catalogued as COSV66081287; called by muse, mutect2, varscan2
- Y_RNA | chr1:31506261 C>T | 5'Flank (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2, varscan2
- ZBED3 | c.*52T>C | 3'UTR (SNP) | VAF 88/183 reads (48%) | called by muse, mutect2, varscan2
- ZBTB3 | c.*305T>A | 3'UTR (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- ZNF142 | c.*182A>G | 3'UTR (SNP) | VAF 73/113 reads (65%) | called by muse, mutect2, varscan2
- ZNF512B | c.*193C>G | 3'UTR (SNP) | VAF 61/143 reads (43%) | called by muse, mutect2, varscan2
- ZNF516 | c.*485T>G | 3'UTR (SNP) | VAF 88/179 reads (49%) | called by muse, mutect2, varscan2
